Somatic mutation profile of tumor specimen MP2PRT-PAPSMF-TMP1-A (aliquot MP2PRT-PAPSMF-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PAPSMF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,111 days).
Specimen MP2PRT-PAPSMF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dbc952d8-6a36-4956-855e-49c0dc238558.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPSMF-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPSMF-NM1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b3f06a4-7765-4891-9a07-1cbeb277a58a

The open-access MAF lists 280 somatic variants for this specimen: 206 protein-altering or splice-affecting, 61 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 182, Silent 61, Nonsense Mutation 21, 3'UTR 4, Intron 4, 5'UTR 3, 5'Flank 2, Splice Region 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA1 | c.3478C>T p.Q1160* | Nonsense Mutation (SNP) | VAF 62/249 reads (25%) | catalogued as rs1420493225; called by muse, mutect2, varscan2
- ADNP | c.2860G>A p.D954N | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.127); catalogued as COSV62424648; called by muse, mutect2
- ANK3 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 16/336 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV55046849; called by muse, mutect2
- BCL2L10 | c.287G>C p.R96T | Missense Mutation (SNP) | VAF 30/294 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV53064155; called by muse, mutect2
- BIRC6 | c.11315C>A p.S3772* | Nonsense Mutation (SNP) | VAF 16/270 reads (6%) | catalogued as COSV70204206; called by muse, mutect2
- CA2 | c.604C>G p.L202V | Missense Mutation (SNP) | VAF 103/294 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV53405932; called by muse, mutect2, varscan2
- CATSPER1 | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 79/211 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1157584569; called by muse, mutect2, varscan2
- CFAP44 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.254); catalogued as COSV55608206; called by muse, mutect2
- CHAMP1 | c.1654C>G p.P552A | Missense Mutation (SNP) | VAF 14/404 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.117); catalogued as rs1555379835; called by muse, mutect2
- CLPB | c.889G>C p.E297Q | Missense Mutation (SNP) | VAF 10/233 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.947); catalogued as COSV53632797; called by muse, mutect2
- CORO1C | c.976G>C p.D326H | Missense Mutation (SNP) | VAF 11/294 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs1444705167; called by muse, mutect2
- CPAMD8 | c.3487G>C p.E1163Q (on ENST00000651564; = p.E1116Q on NM_015692.5) | Missense Mutation (SNP) | VAF 23/454 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV71596731; called by muse, mutect2
- CPS1 | c.562C>T p.Q188* | Nonsense Mutation (SNP) | VAF 14/242 reads (6%) | catalogued as COSV51802685; called by muse, mutect2
- CSMD1 | c.3229C>T p.R1077C (on ENST00000520002; = p.R1076C on NM_033225.6) | Missense Mutation (SNP) | VAF 28/456 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867742507, COSV59279573, COSV59288383; called by muse, mutect2
- CTF1 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 197/532 reads (37%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.556); catalogued as rs1339248960; called by muse, mutect2, varscan2
- DENND4A | c.5402G>C p.R1801T | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV101475342; called by muse, mutect2
- DLG3 | c.2187G>C p.K729N (on ENST00000374360 / NM_021120.4; = p.K424N on NM_020730.3) | Missense Mutation (SNP) | VAF 25/402 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99529432; called by muse, mutect2
- DSG4 | c.2677G>C p.E893Q | Missense Mutation (SNP) | VAF 77/233 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.333); catalogued as COSV57398387; called by muse, mutect2, varscan2
- EHMT2 | c.136C>G p.R46G | Missense Mutation (SNP) | VAF 18/368 reads (5%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV64993781; called by muse, mutect2
- EIF4G3 | c.3490C>T p.Q1164* | Nonsense Mutation (SNP) | VAF 132/372 reads (35%) | catalogued as COSV51694644; called by muse, mutect2, varscan2
- ELOA3C | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 62/1494 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.669); catalogued as COSV99796584; called by muse, mutect2
- EPG5 | c.7240G>C p.E2414Q | Missense Mutation (SNP) | VAF 25/259 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as CM163418; called by muse, mutect2
- ETAA1 | c.1555G>C p.E519Q | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as COSV55473822, COSV55474110; called by muse, mutect2, varscan2
- FAM167A | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 160/420 reads (38%) | SIFT tolerated (0.82); PolyPhen benign (0.093); catalogued as COSV99461363; called by muse, mutect2, varscan2
- GABRP | c.309G>C p.K103N | Missense Mutation (SNP) | VAF 119/320 reads (37%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.645); catalogued as rs748020433; called by muse, mutect2, varscan2
- GORASP1 | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 96/263 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as rs746821695, COSV100073206; called by muse, mutect2, varscan2
- GRAMD1A | c.7G>C p.D3H | Missense Mutation (SNP) | VAF 47/539 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.974); catalogued as COSV58767906; called by muse, mutect2
- HIVEP2 | c.2773G>C p.E925Q | Missense Mutation (SNP) | VAF 19/492 reads (4%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.946); catalogued as COSV99174219; called by muse, mutect2
- IFIH1 | c.2530G>C p.E844Q | Missense Mutation (SNP) | VAF 19/362 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55127005, COSV99718408; called by muse, mutect2
- INSR | c.2981C>A p.S994Y | Missense Mutation (SNP) | VAF 87/256 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57173643; called by muse, mutect2, varscan2
- KLF4 | c.587C>G p.S196W | Missense Mutation (SNP) | VAF 22/597 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV65928958, COSV65929366; called by muse, mutect2
- KLHL5 | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 87/252 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.707); catalogued as rs1368300535; called by muse, mutect2, varscan2
- LYPD3 | c.328C>G p.Q110E | Missense Mutation (SNP) | VAF 110/348 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs537767193; called by muse, mutect2, varscan2
- MAP3K15 | c.2212C>G p.L738V | Missense Mutation (SNP) | VAF 61/194 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV58829395, COSV58835613; called by muse, mutect2, varscan2
- MARCHF7 | c.191C>G p.S64C | Missense Mutation (SNP) | VAF 17/266 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as COSV99034748; called by muse, mutect2
- MB21D2 | c.931C>T p.Q311* | Nonsense Mutation (SNP) | VAF 28/323 reads (9%) | catalogued as COSV66661548, COSV66661553; called by muse, mutect2
- MGARP | c.571G>C p.D191H | Missense Mutation (SNP) | VAF 62/217 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV67449777; called by muse, mutect2, varscan2
- MIA3 | c.3620G>C p.R1207T | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as COSV60509763; called by muse, mutect2, varscan2
- MOCOS | c.1133C>G p.S378C | Missense Mutation (SNP) | VAF 147/340 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV54341396; called by muse, mutect2, varscan2
- MUC16 | c.38321G>A p.R12774H | Missense Mutation (SNP) | VAF 83/212 reads (39%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs548938808, COSV67485780; called by muse, mutect2, varscan2
- MYH14 | c.3120G>C p.K1040N | Missense Mutation (SNP) | VAF 16/342 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV51812285; called by muse, mutect2
- MYH4 | c.4863G>C p.K1621N | Missense Mutation (SNP) | VAF 102/278 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV99700556; called by muse, mutect2, varscan2
- N4BP2L1 | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 45/698 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); catalogued as rs1290457268; called by muse, mutect2
- NCKAP5L | c.601G>C p.D201H | Missense Mutation (SNP) | VAF 20/524 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100259190; called by muse, mutect2
- NUDT16L1 | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 17/499 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.146); catalogued as rs1383997136; called by muse, mutect2
- NUP210L | c.1807C>G p.L603V | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.991); catalogued as COSV55151744, COSV99667613; called by muse, mutect2
- OR4C15 | c.442G>A p.E148K (on ENST00000314644; = p.E94K on NM_001001920.2) | Missense Mutation (SNP) | VAF 138/367 reads (38%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.011); catalogued as COSV58952202; called by muse, mutect2, varscan2
- OTOF | c.469C>T p.R157W | Missense Mutation (SNP) | VAF 117/272 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.249); catalogued as rs778200989; called by muse, mutect2, varscan2
- PAPPA2 | c.2503C>G p.Q835E | Missense Mutation (SNP) | VAF 16/426 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV62781699; called by muse, mutect2
- PARVA | c.364G>C p.D122H | Missense Mutation (SNP) | VAF 91/211 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58516047; called by muse, mutect2, varscan2
- PCCA | c.739C>G p.Q247E | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.021); catalogued as COSV66190373; called by muse, mutect2, varscan2
- PCDH8 | c.2868G>C p.K956N | Missense Mutation (SNP) | VAF 24/361 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV58810674; called by muse, mutect2
- PCDHA8 | c.1365C>G p.F455L | Missense Mutation (SNP) | VAF 22/664 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV65334617; called by muse, mutect2
- PDE5A | c.1095G>C p.Q365H | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV53347988; called by muse, mutect2
- PLA2R1 | c.1289G>C p.G430A | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT tolerated (0.9); PolyPhen benign (0.42); catalogued as rs1287598767; called by muse, mutect2
- POLR2A | c.477G>C p.E159D | Missense Mutation (SNP) | VAF 112/335 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.07); catalogued as COSV59492733; called by muse, mutect2, varscan2
- PPARGC1A | c.1938G>C p.K646N | Missense Mutation (SNP) | VAF 32/289 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV53527786; called by muse, mutect2, varscan2
- PRDM13 | c.1902C>G p.F634L | Missense Mutation (SNP) | VAF 170/503 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.13); catalogued as COSV65029425; called by muse, mutect2, varscan2
- PTPRQ | c.6325C>G p.Q2109E (on ENST00000616559; = p.Q2076E on NM_001145026.2) | Missense Mutation (SNP) | VAF 13/276 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1351355443, CM135928, COSV57046121; called by muse, mutect2
- RAB5C | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 15/348 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60525554; called by muse, mutect2
- RARS2 | c.16C>G p.R6G | Missense Mutation (SNP) | VAF 29/435 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV57638114, COSV57641021; called by muse, mutect2
- RNF10 | c.2059C>A p.L687M | Missense Mutation (SNP) | VAF 76/279 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV100378536, COSV58048290; called by muse, mutect2, varscan2
- RNF213 | c.1756-1G>A p.X586_splice | Splice Site (SNP) | VAF 47/151 reads (31%) | catalogued as rs1023343641; called by muse, mutect2, varscan2
- SCRN1 | c.1206C>G p.F402L | Missense Mutation (SNP) | VAF 18/301 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.39); catalogued as COSV54129749; called by muse, mutect2
- SLC5A4 | c.925C>T p.H309Y | Missense Mutation (SNP) | VAF 18/406 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1452745092; called by muse, mutect2
- SLC66A2 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 23/371 reads (6%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs1289978997, COSV100673887; called by muse, mutect2
- SLC9B1 | c.268C>G p.L90V | Missense Mutation (SNP) | VAF 86/240 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs1171296425, COSV56474433, COSV56475677; called by muse, mutect2, varscan2
- SPANXN2 | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 62/690 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100979769; called by muse, mutect2
- SPATA16 | c.1482C>G p.I494M | Missense Mutation (SNP) | VAF 51/161 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.313); catalogued as COSV63533442; called by muse, mutect2, varscan2
- SPEG | c.7474C>T p.R2492C | Missense Mutation (SNP) | VAF 22/653 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs939871492; called by muse, mutect2
- STOML3 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 104/288 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as rs374030322, COSV65510505, COSV65511300; called by muse, varscan2
- TBX3 | c.1405G>C p.E469Q (on ENST00000257566 / NM_016569.4; = p.E449Q on NM_005996.4) | Missense Mutation (SNP) | VAF 42/806 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as COSV57474349; called by muse, mutect2
- TRPC3 | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 43/667 reads (6%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs922413316; called by muse, mutect2
- TTC7A | c.1131G>C p.Q377H | Missense Mutation (SNP) | VAF 142/390 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV99766498; called by muse, mutect2, varscan2
- TTN | c.70535C>T p.S23512L (on ENST00000591111; = p.S16088L on NM_003319.4) | Missense Mutation (SNP) | VAF 108/266 reads (41%) | PolyPhen benign (0.053); catalogued as rs368058280; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBGCP6 | c.3376C>T p.P1126S | Missense Mutation (SNP) | VAF 49/540 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.062); catalogued as COSV50545087; called by muse, mutect2
- UGT2B15 | c.1130G>A p.G377E | Missense Mutation (SNP) | VAF 56/342 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57736374; called by muse, varscan2
- VPS33A | c.1114G>C p.D372H | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99931206; called by muse, mutect2, varscan2
- ZNF365 | c.718G>T p.E240* | Nonsense Mutation (SNP) | VAF 10/217 reads (5%) | catalogued as COSV67926669; called by muse, mutect2
- ZNF624 | c.313C>G p.H105D | Missense Mutation (SNP) | VAF 67/198 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.068); catalogued as COSV60940066; called by muse, mutect2, varscan2
- ZNF74 | c.629G>A p.R210K | Missense Mutation (SNP) | VAF 19/523 reads (4%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as rs1277129153; called by muse, mutect2
- AC025287.4 | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 12/296 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.099); called by muse, mutect2
- ADGRG4 | c.6053C>G p.S2018C | Missense Mutation (SNP) | VAF 36/555 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.334); called by muse, mutect2
- ADPRHL1 | c.1690G>C p.E564Q | Missense Mutation (SNP) | VAF 18/506 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- AMZ2 | c.71C>G p.S24* | Nonsense Mutation (SNP) | VAF 22/363 reads (6%) | called by muse, mutect2
- ANKRD11 | c.1846G>C p.E616Q | Missense Mutation (SNP) | VAF 16/434 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.107); called by muse, mutect2
- APBA1 | c.816G>C p.Q272H | Missense Mutation (SNP) | VAF 155/403 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- BCORL1 | c.4816C>G p.L1606V | Missense Mutation (SNP) | VAF 146/348 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C4orf51 | c.61C>G p.Q21E | Missense Mutation (SNP) | VAF 67/189 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.041); called by muse, varscan2
- CACTIN | c.1633G>A p.D545N | Missense Mutation (SNP) | VAF 261/572 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- CCDC183 | c.835G>C p.E279Q | Missense Mutation (SNP) | VAF 14/330 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); called by muse, mutect2
- CCDC85C | c.556C>G p.L186V | Missense Mutation (SNP) | VAF 16/508 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.787); called by muse, mutect2
- CDK5RAP2 | c.3200A>G p.E1067G | Missense Mutation (SNP) | VAF 20/310 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.041); called by muse, mutect2
- CEP295 | c.7670T>G p.L2557* | Nonsense Mutation (SNP) | VAF 10/172 reads (6%) | called by muse, mutect2
- CFAP65 | c.2205C>G p.I735M | Missense Mutation (SNP) | VAF 17/472 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.532); called by muse, mutect2
- CHAC1 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 229/273 reads (84%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- CHD5 | c.5648C>T p.S1883F | Missense Mutation (SNP) | VAF 20/558 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CHSY1 | c.2400G>C p.R800S | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- CMYA5 | c.7283G>C p.R2428T | Missense Mutation (SNP) | VAF 65/180 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- CRACD | c.2959G>C p.E987Q | Missense Mutation (SNP) | VAF 13/461 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2
- DARS1 | c.569C>G p.S190* | Nonsense Mutation (SNP) | VAF 9/235 reads (4%) | called by muse, mutect2
- DDX31 | c.572G>C p.R191T | Missense Mutation (SNP) | VAF 130/355 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- DGKH | c.1921G>C p.D641H | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.332); called by muse, mutect2
- DNAH6 | c.7670G>C p.R2557T | Missense Mutation (SNP) | VAF 65/210 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DPH2 | c.1282G>C p.D428H | Missense Mutation (SNP) | VAF 135/290 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- DSC1 | c.2614G>C p.E872Q | Missense Mutation (SNP) | VAF 20/500 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2
- DUS1L | c.888G>C p.K296N | Missense Mutation (SNP) | VAF 107/286 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- EAF1 | c.777G>C p.L259F | Missense Mutation (SNP) | VAF 79/220 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ELAC1 | c.982G>C p.E328Q | Missense Mutation (SNP) | VAF 34/388 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.122); called by muse, mutect2
- EVI5 | c.349C>T p.L117F | Missense Mutation (SNP) | VAF 21/318 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); called by muse, mutect2
- FAAP24 | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 110/316 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- FAM135B | c.1143C>G p.N381K | Missense Mutation (SNP) | VAF 113/276 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- FAM219A | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 189/455 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- FAM43B | c.967G>C p.E323Q | Missense Mutation (SNP) | VAF 136/408 reads (33%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.012); called by muse, varscan2
- FAM71E1 | c.269C>T p.T90M | Missense Mutation (SNP) | VAF 106/258 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAT3 | c.5453C>T p.S1818L | Missense Mutation (SNP) | VAF 17/321 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.117); called by muse, mutect2
- FMO5 | c.472C>G p.L158V | Missense Mutation (SNP) | VAF 14/280 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- FNDC3B | c.1708G>C p.D570H | Missense Mutation (SNP) | VAF 14/396 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- GLYATL3 | c.438C>T p.F146= | Splice Region (SNP) | VAF 11/180 reads (6%) | called by muse, mutect2
- GPRIN3 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 14/390 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.091); called by muse, mutect2
- GTF3C6 | c.163C>G p.L55V | Missense Mutation (SNP) | VAF 14/322 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); called by muse, mutect2
- IGFN1 | c.3694G>C p.E1232Q (on ENST00000295591 / NM_001367841.1; = p.E3689Q on NM_001164586.2) | Missense Mutation (SNP) | VAF 27/408 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.175); called by muse, mutect2
- IRGQ | c.1831G>C p.D611H | Missense Mutation (SNP) | VAF 22/495 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ITGB6 | c.1509G>C p.K503N | Missense Mutation (SNP) | VAF 150/404 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ITPRID2 | c.1726C>T p.Q576* | Nonsense Mutation (SNP) | VAF 127/298 reads (43%) | called by muse, mutect2, varscan2
- KCNG3 | c.879G>C p.M293I | Missense Mutation (SNP) | VAF 14/412 reads (3%) | SIFT tolerated (0.87); PolyPhen benign (0.018); called by muse, mutect2
- KCNH2 | c.655G>C p.D219H | Missense Mutation (SNP) | VAF 227/609 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- KIAA2012 | c.1648C>G p.Q550E | Missense Mutation (SNP) | VAF 17/204 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2
- KLHL20 | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 29/374 reads (8%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.934); called by muse, mutect2
- LRRC8A | c.111G>A p.M37I | Missense Mutation (SNP) | VAF 147/395 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- MAP1B | c.2854G>C p.E952Q | Missense Mutation (SNP) | VAF 28/324 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.852); called by muse, mutect2
- MAP3K1 | c.3880G>C p.E1294Q | Missense Mutation (SNP) | VAF 87/260 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MCC | c.1027G>C p.D343H | Missense Mutation (SNP) | VAF 16/350 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.243); called by muse, mutect2
- MTOR | c.6750C>G p.I2250M | Missense Mutation (SNP) | VAF 34/413 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- NAA15 | c.1807C>G p.Q603E | Missense Mutation (SNP) | VAF 12/209 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.013); called by muse, mutect2
- NAGS | c.665C>G p.S222C | Missense Mutation (SNP) | VAF 22/517 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.038); called by muse, mutect2
- NAV3 | c.5479C>T p.H1827Y (on ENST00000397909 / NM_001024383.2; = p.H1805Y on NM_014903.6) | Missense Mutation (SNP) | VAF 12/316 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); called by muse, mutect2
- NBR1 | c.578C>A p.S193* | Nonsense Mutation (SNP) | VAF 18/386 reads (5%) | called by muse, mutect2
- NDC80 | c.762G>T p.L254= | Splice Region (SNP) | VAF 37/155 reads (24%) | called by muse, mutect2, varscan2
- NUDT16L1 | c.144C>G p.F48L | Missense Mutation (SNP) | VAF 17/508 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.035); called by muse, mutect2
- OLAH | c.693C>G p.Y231* (on ENST00000378228 / NM_001039702.3; = p.Y284* on NM_018324.3) | Nonsense Mutation (SNP) | VAF 71/243 reads (29%) | called by muse, mutect2, varscan2
- OR4X1 | c.255C>G p.I85M | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2
- P4HA3 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 18/430 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, mutect2
- PATJ | c.5173G>A p.D1725N | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PCDHGB2 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 38/351 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PCSK1 | c.332C>G p.S111* | Nonsense Mutation (SNP) | VAF 17/255 reads (7%) | called by muse, mutect2
- PGK1 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 110/315 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- PLK2 | c.513G>C p.L171F | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- POM121L2 | c.2279C>G p.S760* | Nonsense Mutation (SNP) | VAF 35/359 reads (10%) | called by muse, mutect2
- POU2F1 | c.547C>T p.Q183* (on ENST00000541643 / NM_001365848.1; = p.Q206* on NM_002697.4) | Nonsense Mutation (SNP) | VAF 103/261 reads (39%) | called by muse, mutect2, varscan2
- POU3F3 | c.469G>T p.D157Y | Missense Mutation (SNP) | VAF 44/754 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.522); called by muse, mutect2
- PPFIA2 | c.889C>T p.R297* | Nonsense Mutation (SNP) | VAF 102/263 reads (39%) | called by muse, mutect2, varscan2
- PRKAB2 | c.598G>C p.E200Q | Missense Mutation (SNP) | VAF 107/291 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- PTPRZ1 | c.5164G>C p.E1722Q | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.398); called by muse, mutect2
- R3HCC1L | c.1540G>C p.D514H | Missense Mutation (SNP) | VAF 101/250 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- REXO1 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 173/447 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RHPN1 | c.392C>A p.S131* | Nonsense Mutation (SNP) | VAF 20/358 reads (6%) | called by muse, mutect2
- RIMBP3 | c.3419A>C p.D1140A | Missense Mutation (SNP) | VAF 166/1518 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); called by mutect2, varscan2
- RNF40 | c.2458C>G p.Q820E | Missense Mutation (SNP) | VAF 13/250 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.405); called by muse, mutect2
- RP1L1 | c.5563G>A p.E1855K | Missense Mutation (SNP) | VAF 21/359 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.354); called by muse, mutect2
- RP1L1 | c.4201G>C p.E1401Q | Missense Mutation (SNP) | VAF 112/338 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- SDHAF4 | c.41C>A p.S14* | Nonsense Mutation (SNP) | VAF 130/383 reads (34%) | called by muse, mutect2, varscan2
- SERPINA10 | c.1154G>C p.R385T | Missense Mutation (SNP) | VAF 10/219 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); called by muse, mutect2
- SETD5 | c.2621C>G p.S874C | Missense Mutation (SNP) | VAF 125/357 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- SETX | c.2575C>G p.Q859E | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2
- SH3GLB2 | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 14/412 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- SLC25A19 | c.910G>C p.E304Q | Missense Mutation (SNP) | VAF 113/320 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMARCA2 | c.3626C>G p.S1209* | Nonsense Mutation (SNP) | VAF 119/288 reads (41%) | called by muse, mutect2, varscan2
- SMPD1 | c.1396G>C p.E466Q | Missense Mutation (SNP) | VAF 108/324 reads (33%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- SP3 | c.1939G>A p.G647R | Missense Mutation (SNP) | VAF 19/374 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SPG11 | c.7124C>G p.S2375C | Missense Mutation (SNP) | VAF 55/83 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- SRCAP | c.4858C>G p.P1620A | Missense Mutation (SNP) | VAF 97/257 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SRCAP | c.5134C>G p.P1712A | Missense Mutation (SNP) | VAF 143/365 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ST7L | c.1119G>C p.L373F | Missense Mutation (SNP) | VAF 10/264 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- STYXL2 | c.1891G>C p.E631Q | Missense Mutation (SNP) | VAF 145/428 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SULT1E1 | c.673C>G p.H225D | Missense Mutation (SNP) | VAF 97/259 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SUMO4 | c.238G>C p.D80H | Missense Mutation (SNP) | VAF 94/274 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2
- SYNGAP1 | c.3507G>C p.E1169D | Missense Mutation (SNP) | VAF 31/562 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.924); called by muse, mutect2
- SZT2 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 122/368 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- TANC1 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 110/322 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- TBC1D12 | c.1329G>C p.M443I | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- TBC1D8B | c.3152G>C p.G1051A | Missense Mutation (SNP) | VAF 14/398 reads (4%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2
- TBCEL | c.901G>C p.E301Q | Missense Mutation (SNP) | VAF 18/225 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TDRD9 | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 54/170 reads (32%) | called by muse, mutect2, varscan2
- TDRKH | c.1033G>C p.E345Q | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0.09); called by muse, mutect2
- THOC1 | c.791C>G p.S264C | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TOR1AIP2 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 14/402 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); called by muse, mutect2
- TRMT61B | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 42/412 reads (10%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2
- TXNDC16 | c.2007G>C p.K669N | Missense Mutation (SNP) | VAF 14/233 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.085); called by muse, mutect2
- UBXN4 | c.449G>C p.R150T | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2
- UGT2B17 | c.1130G>A p.G377E | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP9X | c.3132G>C p.M1044I | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2
- USPL1 | c.377G>A p.R126K | Missense Mutation (SNP) | VAF 25/219 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- VAV1 | c.2005C>T p.H669Y | Missense Mutation (SNP) | VAF 91/267 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- VENTX | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 52/674 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.839); called by muse, mutect2
- VPS28 | c.523G>C p.E175Q | Missense Mutation (SNP) | VAF 16/517 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.309); called by muse, mutect2
- VPS35L | c.296G>C p.R99T | Missense Mutation (SNP) | VAF 9/199 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.544); called by muse, mutect2
- WASF1 | c.706G>C p.E236Q | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.031); called by muse, mutect2
- WDR41 | c.1016C>G p.S339* | Nonsense Mutation (SNP) | VAF 15/223 reads (7%) | called by muse, mutect2
- ZHX3 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 16/409 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.199); called by muse, mutect2
- ZNF132 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 28/300 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZNF682 | c.778G>C p.E260Q | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.734); called by muse, mutect2
- ZNF776 | c.619C>G p.H207D | Missense Mutation (SNP) | VAF 114/363 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- ZNF782 | c.1690T>C p.C564R | Missense Mutation (SNP) | VAF 21/338 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF837 | c.935C>G p.S312C | Missense Mutation (SNP) | VAF 192/510 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- ZXDA | c.900C>G p.F300L | Missense Mutation (SNP) | VAF 191/582 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ABCB4 | c.2886C>T p.L962= | Silent (SNP) | VAF 84/201 reads (42%) | catalogued as COSV55935609; called by muse, mutect2, varscan2
- ABHD11 | c.93C>T p.F31= | Silent (SNP) | VAF 31/668 reads (5%) | catalogued as COSV56106424; called by muse, mutect2
- AQR | c.3648A>G p.L1216= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as rs1274461521; called by muse, mutect2, varscan2
- ARID2 | c.5232G>C p.L1744= | Silent (SNP) | VAF 108/336 reads (32%) | catalogued as COSV57603825; called by muse, mutect2, varscan2
- ARMC5 | c.2124C>G p.L708= | Silent (SNP) | VAF 19/541 reads (4%) | catalogued as rs1037083298; called by muse, mutect2
- CARD11 | c.2532G>A p.V844= | Silent (SNP) | VAF 34/492 reads (7%) | catalogued as rs1185269859; called by muse, mutect2
- CFAP61 | c.3372C>T p.L1124= | Silent (SNP) | VAF 90/266 reads (34%) | called by muse, mutect2, varscan2
- CYP2S1 | c.135C>G p.L45= | Silent (SNP) | VAF 18/574 reads (3%) | called by muse, mutect2
- DHCR7 | c.1107C>T p.L369= | Silent (SNP) | VAF 14/384 reads (4%) | catalogued as rs1169626168, COSV62796098; called by muse, mutect2
- DHX38 | c.2370C>A p.I790= | Silent (SNP) | VAF 26/274 reads (9%) | catalogued as COSV51700970; called by muse, mutect2
- F8 | c.4860G>A p.L1620= | Silent (SNP) | VAF 20/352 reads (6%) | called by muse, mutect2
- FAM186A | c.2943G>A p.Q981= | Silent (SNP) | VAF 102/335 reads (30%) | called by muse, mutect2, varscan2
- FLNB | c.159G>C p.L53= | Silent (SNP) | VAF 26/470 reads (6%) | called by muse, mutect2
- FLT4 | c.2061C>G p.L687= | Silent (SNP) | VAF 137/401 reads (34%) | called by muse, mutect2, varscan2
- FMN2 | c.828C>G p.L276= | Silent (SNP) | VAF 234/672 reads (35%) | called by muse, mutect2, varscan2
- FMN2 | c.2671C>T p.L891= | Silent (SNP) | VAF 174/352 reads (49%) | catalogued as COSV100144729, COSV60420070; called by muse, mutect2, varscan2
- FNDC3A | c.1011C>T p.L337= (on ENST00000492622 / NM_001079673.2; = p.L281= on NM_014923.5) | Silent (SNP) | VAF 12/196 reads (6%) | called by muse, mutect2
- GPR1 | c.618G>C p.L206= | Silent (SNP) | VAF 96/269 reads (36%) | called by muse, mutect2, varscan2
- HSD3B1 | c.870G>A p.L290= | Silent (SNP) | VAF 123/355 reads (35%) | catalogued as rs1240428524; called by muse, mutect2, varscan2
- IGHMBP2 | c.144G>A p.L48= | Silent (SNP) | VAF 34/413 reads (8%) | called by muse, mutect2
- JAML | c.270G>A p.L90= (on ENST00000356289 / NM_001098526.2; = p.L80= on NM_153206.3) | Silent (SNP) | VAF 20/363 reads (6%) | called by muse, mutect2
- KIF26A | c.240C>G p.L80= | Silent (SNP) | VAF 40/595 reads (7%) | called by muse, mutect2
- KIF26B | c.4659C>T p.L1553= | Silent (SNP) | VAF 36/618 reads (6%) | called by muse, mutect2
- KITLG | c.378A>T p.S126= | Silent (SNP) | VAF 11/96 reads (11%) | called by muse, mutect2, varscan2
- MAP3K7CL | c.477C>T p.F159= | Silent (SNP) | VAF 22/356 reads (6%) | catalogued as COSV99726410; called by muse, mutect2
- MAPK4 | c.870G>A p.E290= | Silent (SNP) | VAF 18/257 reads (7%) | catalogued as COSV68544424; called by muse, mutect2
- MATK | c.882G>C p.V294= (on ENST00000310132 / NM_139355.3; = p.V295= on NM_002378.4) | Silent (SNP) | VAF 145/433 reads (33%) | called by muse, mutect2, varscan2
- MRTFB | c.3228C>G p.L1076= (on ENST00000571589 / NM_001365412.2; = p.L1026= on NM_014048.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 123/311 reads (40%) | called by muse, mutect2, varscan2
- MYH14 | c.4716G>A p.L1572= | Silent (SNP) | VAF 16/416 reads (4%) | catalogued as COSV51828922, COSV99224269; called by muse, mutect2
- MYO9A | c.5292G>T p.G1764= | Silent (SNP) | VAF 25/150 reads (17%) | called by muse, mutect2, varscan2
- PKHD1 | c.8424C>T p.G2808= | Silent (SNP) | VAF 119/260 reads (46%) | catalogued as rs181741077; called by muse, mutect2, varscan2
- PLAUR | c.945C>T p.L315= | Silent (SNP) | VAF 16/496 reads (3%) | called by muse, mutect2
- POLR2B | c.3210C>T p.L1070= | Silent (SNP) | VAF 19/285 reads (7%) | catalogued as COSV58900036; called by muse, mutect2
- PPEF2 | c.369C>G p.L123= | Silent (SNP) | VAF 17/298 reads (6%) | catalogued as COSV54425262; called by muse, mutect2
- PRG3 | c.480C>G p.V160= | Silent (SNP) | VAF 22/272 reads (8%) | called by muse, mutect2
- PTPN21 | c.372G>A p.L124= | Silent (SNP) | VAF 29/88 reads (33%) | called by muse, mutect2, varscan2
- QSOX2 | c.960G>A p.S320= | Silent (SNP) | VAF 96/219 reads (44%) | catalogued as rs770914309; called by muse, mutect2
- RBPMS | c.171C>G p.L57= | Silent (SNP) | VAF 6/136 reads (4%) | called by muse, mutect2
- RMI2 | c.231G>C p.P77= | Silent (SNP) | VAF 198/589 reads (34%) | catalogued as rs759054808; called by muse, mutect2, varscan2
- SALL4 | c.3024G>A p.V1008= | Silent (SNP) | VAF 36/373 reads (10%) | catalogued as COSV53850051; called by muse, mutect2
- SCN10A | c.4752C>G p.L1584= | Silent (SNP) | VAF 23/336 reads (7%) | called by muse, mutect2
- SETD5 | c.1743G>A p.Q581= | Silent (SNP) | VAF 15/304 reads (5%) | called by muse, mutect2
- SGSM3 | c.882C>G p.L294= | Silent (SNP) | VAF 135/359 reads (38%) | called by muse, mutect2, varscan2
- SHOC1 | c.162C>A p.V54= | Silent (SNP) | VAF 13/320 reads (4%) | catalogued as COSV100597725; called by muse, mutect2
- SLC26A11 | c.471C>T p.F157= | Silent (SNP) | VAF 10/337 reads (3%) | catalogued as rs1173241537; called by muse, mutect2
- SULF2 | c.93G>C p.L31= | Silent (SNP) | VAF 138/389 reads (35%) | catalogued as COSV100737358, COSV63419386; called by muse, mutect2, varscan2
- SYT3 | c.1317C>G p.L439= | Silent (SNP) | VAF 22/242 reads (9%) | called by muse, mutect2
- THBS1 | c.36G>C p.L12= | Silent (SNP) | VAF 96/149 reads (64%) | catalogued as COSV99527428; called by muse, mutect2, varscan2
- TMEM158 | c.174C>T p.P58= | Silent (SNP) | VAF 245/542 reads (45%) | called by muse, mutect2, varscan2
- TRAPPC12 | c.894G>A p.L298= | Silent (SNP) | VAF 68/438 reads (16%) | called by muse, mutect2, varscan2
- TRIAP1 | c.84C>G p.L28= | Silent (SNP) | VAF 18/483 reads (4%) | catalogued as COSV99985112; called by muse, mutect2
- TRIM4 | c.522C>T p.V174= | Silent (SNP) | VAF 97/303 reads (32%) | called by muse, mutect2, varscan2
- TTN | c.102525C>T p.F34175= (on ENST00000591111; = p.F26751= on NM_003319.4) | Silent (SNP) | VAF 15/317 reads (5%) | called by muse, mutect2
- TUBB6 | c.405C>T p.L135= | Silent (SNP) | VAF 16/494 reads (3%) | called by muse, mutect2
- TUBE1 | c.1320C>T p.F440= | Silent (SNP) | VAF 26/356 reads (7%) | called by muse, mutect2
- UNC79 | c.5535C>T p.V1845= (on ENST00000393151 / NM_001346218.2; = p.V1668= on NM_020818.5) | Silent (SNP) | VAF 43/363 reads (12%) | called by muse, mutect2, varscan2
- UNC80 | c.8052G>A p.Q2684= | Silent (SNP) | VAF 11/232 reads (5%) | called by muse, mutect2
- URB1 | c.5025C>G p.L1675= | Silent (SNP) | VAF 131/353 reads (37%) | called by muse, mutect2, varscan2
- USP26 | c.1203C>G p.L401= | Silent (SNP) | VAF 16/314 reads (5%) | called by muse, mutect2
- VGLL2 | c.642C>G p.L214= | Silent (SNP) | VAF 218/610 reads (36%) | catalogued as rs551063658; called by muse, mutect2
- XKR5 | c.1632C>T p.F544= | Silent (SNP) | VAF 20/387 reads (5%) | called by muse, mutect2
- ARHGEF9 | c.1370-442G>C | Intron (SNP) | VAF 12/300 reads (4%) | called by muse, mutect2
- CD247 | c.*793C>T | 3'UTR (SNP) | VAF 12/291 reads (4%) | called by muse, mutect2
- CHTF8 | c.141+118C>G | Intron (SNP) | VAF 114/336 reads (34%) | called by muse, mutect2, varscan2
- GPR6 | chr6:109978789 C>G | 5'Flank (SNP) | VAF 150/359 reads (42%) | called by muse, mutect2, varscan2
- HUNK | c.*1065C>G | 3'UTR (SNP) | VAF 112/355 reads (32%) | called by muse, mutect2, varscan2
- LRRC59 | c.105+17G>C | Intron (SNP) | VAF 159/503 reads (32%) | catalogued as rs1043402732, COSV56815033; called by muse, mutect2, varscan2
- MINAR1 | c.-1C>G | 5'UTR (SNP) | VAF 7/83 reads (8%) | catalogued as COSV100549300; called by muse, mutect2
- NANP | c.*2072G>A | 3'UTR (SNP) | VAF 63/228 reads (28%) | called by muse, mutect2, varscan2
- RAP1B | c.-47G>C | 5'UTR (SNP) | VAF 13/394 reads (3%) | called by muse, mutect2
- RGS6 | c.1368+11009G>C | Intron (SNP) | VAF 106/290 reads (37%) | called by muse, mutect2, varscan2
- VEGFA | chr6:43770983 G>C | 5'Flank (SNP) | VAF 16/594 reads (3%) | called by muse, mutect2
- WASL | c.-167C>G | 5'UTR (SNP) | VAF 136/417 reads (33%) | catalogued as COSV99771685; called by muse, mutect2, varscan2
- WDR64 | c.*110C>G | 3'UTR (SNP) | VAF 91/269 reads (34%) | called by muse, mutect2, varscan2
